Gene-level copy-number profile of tumor specimen TCGA-02-0456-01A from TCGA case TCGA-02-0456, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.9 years (24,796 days).
Specimen TCGA-02-0456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.380a77b6-6b79-4e67-8426-594c1be4c073.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,958 have no estimate.
https://portal.gdc.cancer.gov/files/0f0a825d-4fc6-4578-a7eb-0d525ced3e56

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,638; copy number 2: 40,460; copy number 3: 3,567.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0456-01): tumor purity 0.45, ploidy 1.89, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
